Gene-level copy-number profile of specimen HCM-SANG-0300-C15-85A from HCMI case HCM-SANG-0300-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0300-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 51f36019-0ddc-4ed3-bd7e-d611e8b72995.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0300-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/eca7c344-ba91-46db-9509-5cbec5d4e328

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 68; copy number 2: 18,100; copy number 3: 5,517; copy number 4: 33,382; copy number 5: 126; copy number 6: 1,418; copy number 7: 26; copy number 8: 201; copy number 10: 60; copy number 11: 8; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 70 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:63,228,315–66,623,102, 42 genes, copy number 10 (within-gene range 2–10): SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2, LINC02040, MAGI1, AC121493.1, ILF2P1, RPL17P17, MAGI1-IT1, MAGI1-AS1, Y_RNA, AC106827.1, SLC25A26, RNU6-787P, RN7SL482P, LRIG1, AC104440.1.
- chr10:62,339,553–64,693,446, 28 genes, copy number 10–13: AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35.

Autosomal genes at a single copy (total copy number 1): 68. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
